Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0DO, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0DO-TTP1-A (Primary Tumor).

[page 1 of 22]
RESULTS REPORTING SYSTEM
AS OF: [REDACTED]

+2

Referred By: [REDACTED] Svc: INPT Dict: [REDACTED]

DRAFT

+3

MRG ID: [REDACTED]

Path-Left temporal biopsy

SURGERY DATE: [REDACTED]

TISSUE: Left temporal biopsy

+2

CLINICAL BRIEF: Left temporal brain tumor. Left temporal craniotomy.

PATHOLOGIC DIAGNOSIS

Left temporal brain biopsies x2:
- glioblastoma, WHO grade 4

GROSS

Received are 2 separate specimens labeled

1. Received fresh for frozen section are three irregular, glistening and tan-pink fragments of tissue each measuring 6 mm in greatest dimension. Cytology touch preparation slides are made and one of the fragments is submitted for frozen section with subsequent permanent sections.

FROZEN SECTION DIAGNOSIS: High grade glioma, possibly glioblastoma. As per [REDACTED]. FS-1, IT-1 [REDACTED]

2. Left temporal brain tumor. Received in formalin are several irregular focally necrotic appearing, firm, glistening and tan-pink to gray-white fragments of tissue measuring 3 x 2.9 x 2 cm in aggregate. Multiple representative sections are submitted. RS-3

MICROSCOPIC

Both biopsies reveal similar findings. Sections reveal a highly malignant tumor composed of glial cells with cellular processes. The tumor cells demonstrate marked nuclear pleomorphism with increased mitoses. Pseudopalisading necrosis and microvascular proliferation are both present. GFAP immunostain is diffusely positive in tumor cells, confirming the astrocytic differentiation of the tumor. The findings are most consistent with glioblastoma multiforme, WHO grade 4.

[page 2 of 22]
Transcription

Type	ID	Date and Time	Dictating Provider
Diagnostic imaging			
Document Text		+3	

MRI

+3

MRI BRAIN

INDICATIONS

Followup craniotomy.

COMPARISON

-7

MRI brain,

TECHNIQUE

T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images and T2 axial FLAIR sequence. No IV contrast was administered. T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images and T2 axial FLAIR sequence. Either postgadolinium SPGR or T1-weighted spin-echo axial images were then obtained through the brain. 15 mL of Magnevist 469 mg/mL was used without complication.

FINDINGS

In the interval, there has been a left parietotemporal craniotomy with a bone flap in situ. The previously identified enhancing mass in the cortex of the lateral left temporal lobe has been removed or debulked in the interval. There are foci of magnetic susceptibility artifact at the resection site from recent surgery and/or bubbles of gas. The remainder of the cavity demonstrates increased signal intensity on both T1 and T2 in keeping with either extracellular methemoglobin from blood degradation products or proteinaceous fluid. There is mild T2 hyperintensity in the adjacent brain parenchyma in keeping with gliosis. There are 2 punctate foci of enhancement in the brain parenchyma surrounding the cavity that are nonspecific. There is enhancement of the dura. There is a small fluid collection in the overlying subdural space immediately deep to the craniotomy.

The midline of the brain is central. The ventricles and basal cisterns are normal. Negative for mass effect. The intracranial flow voids are maintained. The dural venous sinuses enhance normally.

SUMMARY

Status post surgical resection of a solid tumor in the cortex of the lateral left temporal lobe. The surgical cavity has been described above. It contains material in keeping with either blood degradation product or proteinaceous fluid. There are 2 punctate foci of enhancement in the surrounding brain parenchyma that may represent perilesional vessels rather than residual tumor. Followup imaging is advised.

;

[page 3 of 22]
Electronically Signed by:

MRI

Control Number			
Date	Loc.	#Film	Init

Patient Name: [REDACTED]
HR #: [REDACTED]
Date of Birth: [REDACTED]
Sex: F
Phone Numbers: Home: [REDACTED] +2
+0
Visit Date: [REDACTED] Ordered: [REDACTED]
Encounter: [REDACTED]
Authorizing: [REDACTED]
Visit Site: [REDACTED]
Copy to: [REDACTED]

+2
Order Date: [REDACTED]
Ordering User: [REDACTED]
Attending Provider: [REDACTED]
Authorizing Provider: [REDACTED]
Department: [REDACTED]
[REDACTED] MRI BRAIN OTHER. [REDACTED]
STANDING ORDER
Count Left/Total: 0/1

Transcription
Diagnostic imaging +3
Dictation date: [REDACTED]
[REDACTED]
Document text:

MRI
+3
[REDACTED] MRI BRAIN

INDICATIONS
Followup craniotomy.

COMPARISON
[REDACTED]

[page 4 of 22]
[REDACTED]

MRI brain, [REDACTED]

[REDACTED]

TECHNIQUE

T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images and T2 axial FLAIR sequence. No IV contrast was administered. T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images and T2 axial FLAIR sequence. Either postgadolinium SPGR or T1-weighted spin-echo axial images were then obtained through the brain. 15 mL of Magnevist 469 mg/mL was used without complication.

FINDINGS

In the interval, there has been a left parietotemporal craniotomy with a bone flap in situ. The previously identified enhancing mass in the cortex of the lateral left temporal lobe has been removed or debulked in the interval. There are foci of magnetic susceptibility artifact at the resection site from recent surgery and/or bubbles of gas. The remainder of the cavity demonstrates increased signal intensity on both T1 and T2 in keeping with either extracellular methemoglobin from blood degradation products or proteinaceous fluid. There is mild T2 hyperintensity in the adjacent brain parenchyma in keeping with gliosis. There are 2 punctate foci of enhancement in the brain parenchyma surrounding the cavity that are nonspecific. There is enhancement of the dura. There is a small fluid collection in the overlying subdural space immediately deep to the craniotomy.

The midline of the brain is central. The ventricles and basal cisterns are normal. Negative for mass effect. The intracranial flow voids are maintained. The dural venous sinuses enhance normally.

SUMMARY

Status post surgical resection of a solid tumor in the cortex of the lateral left temporal lobe. The surgical cavity has been described above. It contains material in keeping with either blood degradation product or proteinaceous fluid. There are 2 punctate foci of enhancement in the surrounding brain parenchyma that may represent perilesional vessels rather than residual tumor. Followup imaging is advised.

[REDACTED]

[REDACTED]

[REDACTED]

[page 5 of 22]
Transcription

Type	ID	Date and Time	Dictating Provider
------	----	---------------	--------------------

Diagnostic imaging			
--------------------	--	--	--

Document Text

+121

MRI

+121

MRI BRAIN

HISTORY

Followup glioblastoma multiforme status post gross total resection, Gliadel wafer, and radiation therapy. No new symptoms.

TECHNIQUE

T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images. Either postgadolinium SPGR or T1-weighted spin-echo axial images were then obtained through the brain. The amount of gadolinium was 15 mL. Then additional coronal SPGR postgadolinium images were obtained.

COMPARISON

(1 day postoperative).

+3

FINDINGS

Overall the left posterior temporal lobe resection cavity has decreased with resorption of the previous surgical hypointense packing material/wafers. There is new FLAIR signal abnormality along the rim of the resection cavity most prominent medially with corresponding moderate thickness section cavity wall enhancement along with medial extension at site of previous focus of abnormal enhancement seen on prior series 8 image 23. This may represent a combination of section cavity granulation tissue and residual tumor especially along the medial aspect of the section cavity. Overall the area of signal abnormality measures 3.7 x 3.0 x 2.0 cm, previously 4.7 x 2.6 x 2.3 cm (given the larger dimension of resection cavity from the prior exam). The amount of postoperative extraaxial fluid has resolved. Left dural enhancement overlying the site of left temporal craniotomy is redemonstrated. The resection cavity demonstrates a marginal T1 shortening pattern with postsurgical hemorrhagic products, overall decreased compared to the prior exam.

No midline shift or hydrocephalus. Ventricles, sulci, and cisterns are not effaced. There is mild ethmoid, maxillary, and sphenoid sinus mucosal thickening. The mastoids are clear. The orbits are normal.

IMPRESSION

Left temporal resection cavity moderate thick peripheral enhancement with mild medial extension concerning for residual tumor and superimposed granulation tissue. This study can serve as a baseline for further followups.

;

[page 6 of 22]
Results

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST (Accession [REDACTED])

Encounter

[View Encounter](#)

PACS Images

[Show images for MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST](#)

Future Appts

Result Information

	Status	+206	Provider Status
Normal	Final result (Exam End: AM)	[REDACTED]	Open

Patient Release Status:

This result is not viewable by the patient.

Study Result

[REDACTED] +206

MRI BRAIN

HISTORY:

[REDACTED] female with history of glioblastoma status post resection and radiation, now chemotherapy.

PROCEDURE:

T1-weighted spin-echo sagittal and axial images were obtained through the brain followed by intermediate and T2-weighted fast spin-echo axial images. Either postgadolinium SPGR or T1-weighted spin-echo axial images were then obtained through the brain. 14 ml of Magnevist 469 mg/ml was used without complication.

COMPARISON:

+161 [REDACTED] and [REDACTED] +121

FINDINGS:

Previous described finding of rim enhancing hyperintense T2 signal 3.5 x 2 cm left temporal lobe, irregular enhancing lesion, abutting the adjacent meninges, has decreased in the interval size measurement of 2.5 x 1.5 cm in the greatest dimension. Findings likely represent resolving post procedural, therapeutic gliosis/scarring and/or residual neoplasm. No new enhancing mass. No abnormal fluid collections.

No intracranial hemorrhage. No brain edema, herniation, hydrocephalus, or shift of the midline structures. Posterior fossa, cerebellum, and brain stem appear normal. Bilateral mastoid air cells, bilateral maxillary, sphenoid, and frontal sinuses are clear. Mild mucosal thickening of ethmoid sinus.

IMPRESSION:

Left temporal craniotomy defect status post resection of glioblastoma with interval decreased size of irregular enhancing hyperintense T2 signal left temporal lobe lesion from prior measurement of 3.5 x 2 cm in the greatest

[page 7 of 22]
[REDACTED]
dimension to the current measurement of 2.5 x 1.5 cm. No new enhancing mass or abnormal fluid collections.

D: [REDACTED]
T: [REDACTED]
D: [REDACTED] +206
T: [REDACTED] +206

Scans on Order [REDACTED]
[REDACTED]

Result History

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST (Order [REDACTED] on [REDACTED] - Order Result History Report +206

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
MRI BRAIN WOW CONTRAST	Final	[REDACTED]	[REDACTED]
		+206	+206

Staff Information

Technologist	Transcriptionist	Assigned Physician(s)	Assigned Pool(s)
[REDACTED]	N/A	N/A	N/A

Verification Information

Signed By	Signed On
[REDACTED]	[REDACTED] +210

Order

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST [REDACTED]

Print Result Report
report

Order

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST [REDACTED]

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST [REDACTED] Order #: [REDACTED]
[REDACTED]

Encounter

View Encounter

Order Information

Electronically Authorized By	Electronically Ordered By
[REDACTED]	[REDACTED]

Authorizing Provider

Authorizing Provider	Billing Provider
[REDACTED]	[REDACTED]

[page 8 of 22]
Assoc. Dx

CA BRAIN, CEREBRUM, GBM surgery +2

Priority and Order Details

Priority	Order Status	Class
Routine	Completed	Normal

Future Order Information

Expected
+206

Order Questions

Question	Answer	Comment
Any contraindications for MRI?	NONE	
PRIORITY	1) ROUTINE (7-10 DAYS)	
Note: Please pick one selection		
CLAUSTROPHOB	NO	
Note: Press F5 for a list of options		
Does patient require oxygen?	NO	
Is the patient on Renal Dialysis?	NO	

Comments

This order is appropriate for clinical suspicion for stroke, brain neoplasm, seizure, multiple sclerosis. Clinical History (symptom or diagnosis, not a "rule out", including information that would be helpful to the Radiologist, such as location, duration, etc): F with GBM s/p resection, gliadel wafer, XRT and now chemo. Please eval for response to therapy, compare to previous scan. Thank you. GFR (MDRD method) is >90 ml/min/1.73m2 body surface area, normal. Based on serum creatinine: CR 0.6 Weight: 148 lbs 9.6 oz Has this patient had this study before? Yes. +188 +190

Cosign Order Info

Action	Created on	Responsible Provider	Signed by	Signed on
Ordering				
	+206			+206

Order Tracking Information

MRI BRAIN WO CONTRAST, FOLLOWED BY CONTRAST
+206

[page 9 of 22]
Results

MRI BRAIN WO/W CONTRAST

Encounter

[View Parent Encounter](#)

PACS Images

[Show images for MRI BRAIN WO/W CONTRAST](#)

Future Appts

Result Information

Status

Provider Status

Reviewed

Patient Release Status:

This result is not viewable by the patient.

Study Result

EXAM: MRI BRAIN WO/W CONTRAST

EXAM DATE AND TIME: +3297

HISTORY: female with left temporal glioblastoma multiforme status post resection COMPARISON: +3117, +2925, +2740

Technique: Axial T1, axial FLAIR, axial T2, axial GRE, sagittal T1 FSPGR, DWI/ADC. Post gadolinium T1 in 3 planes.

5 ml of Gadavist administered intravenously without incident.

FINDINGS:

Cerebral parenchyma: Stable postsurgical changes from left parietal-temporal craniotomy with expected dural thickening and enhancement. Left temporal resection cavity measures approximately 1 x 1.2 x 1.5 cm AP X TRV X CC noted on images 18/11-14/9 compared to previous image 18/9, and 14/10.

The associated cerebral edema/gliosis in the left temporal lobe remains stable.

No imaging evidence to suggest recurrent or residual disease. No new foci of abnormal brain parenchymal enhancement.

Extra axial spaces: normal in size and morphology for the patient's age.

Ventricular system: Stable asymmetry of the bodies of the lateral ventricles with prominence noted on the left. Mild ex vacuo dilatation of the left occipital horn of the lateral ventricle unchanged.

Basal cisterns: normal.

Midline shift: none.

Sella: unremarkable.

Cerebellum: normal

Brainstem: normal

[page 10 of 22]
[REDACTED]: No restricted diffusion to suggest acute ischemic injury.
Vascular system: appropriate arterial and dural sinus flow voids.
Visualized Paranasal sinuses: Minimal mucosal disease involving ethmoid air cells and both maxillary sinuses
Visualized Orbits: unremarkable.
Visualized upper cervical spine: unremarkable.
Skull: unremarkable.

IMPRESSION:

No significant interval change in the left temporal lobe postsurgical cavity. No imaging evidence to suggest residual or recurrent tumor. Stable cerebral edema/gliosis centered at the left temporal lobe with ex vacuo dilatation of the left occipital horn of the lateral ventricle.

No acute infarct.

This record was prepared with assistance of voice recognition technology. If clarification or correction is needed for patient care, please contact the author of this report. Inadvertent errors in documentation due to improper speech recognition is possible due to this.

Electronically signed by [REDACTED] +3298

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
MRI BRAIN WOW CONTRAST	Final	[REDACTED]	[REDACTED]
		+3297	+3297

Staff Information

Technologist	Transcriptionist	Assigned Physician(s)	Assigned Pool(s)
[REDACTED]	N/A	N/A	N/A

Verification Information

Signed By	Signed On
[REDACTED]	[REDACTED]
	+3298

Result Notes

[REDACTED]
[REDACTED]
+3299

Please tell [REDACTED] that her MRI looks great. No signs of cancer recurrence or progression. yay!

[REDACTED]
[REDACTED]
+3299

Order

MRI BRAIN [REDACTED]

Print Result Report
report

[page 11 of 22]
Result Notes

+3299

Please tell [REDACTED] that her MRI looks great. No signs of cancer recurrence or progression. yay!

Order

MRI BRAIN WO/W CONTRAST [REDACTED]

MRI BRAIN WO/W CONTRAST [REDACTED]

Original Order Name (If blank, same as above):

MRI BRAIN (surveillance)

Encounter

View Parent Encounter

Order Information

Electronically Authorized By

Electronically Ordered By

Authorizing Provider

Authorizing Provider

Billing Provider

Assoc. Dx

**GLIOBLASTOMA MULTIFORME, TEMPORAL LOBE
COMPLEX PARTIAL TEMPORAL LOBE EPILEPSY**

Priority and Order Details

Priority	Order Status	Class
Routine	Completed	Normal

Order Questions

Question	Answer	Comment
Any contraindications for MRI?	1.NONE	
CLAUSTROPHOB	No	
Note: Press F5 for a list of options		
Does patient require oxygen?	No	
Type of Pre-approval	WRITTEN ORDER	
Note: Verbal, written or protocol		

Comments

CLINICAL CONCERN: Needs surveillance scan. (differential diagnosis or r/o)

Wt Readings from Last 1 Encounters:

[REDACTED]: 112 lb (50.8 kg)

+3221

Scheduling Instructions

MRI Instructions: READ CAREFULLY and SAVE

Your Provider has ordered a MRI Scan for you. The MRI Department will call you to

[page 12 of 22]
[REDACTED] schedule this appointment. If you do not hear from them within 5 days please call the MRI department at [REDACTED] between the hours of 8 AM to 8 PM, seven days a week. Once scheduled you may also be contacted by Pre-Registration prior to your MRI.

If you had an MRI exam today as a result of your ER visit, please disregard these instructions.

[REDACTED]

[REDACTED]

SPÉCIAL INSTRUCTIONS:

For your SAFETY all body piercings must be removed prior to the MRI or the appointment may be rescheduled.

We WILL NOT be able to do an MRI if you have a Pacemaker.

We MAY NOT be able to do an MRI if you have any of the following:

- > Some/most cerebral aneurysm clips

[page 13 of 22]
- > Artificial heart valve
- > A metallic foreign body embedded in your eye
- > If you are renal compromised, on dialysis or are in kidney failure

*If you have any of the above items, please discuss this with your referring Provider.

*If your have piercings that cannot be removed, please let us know when scheduling your appointment.

WHAT TO EXPECT DURING YOUR MRI APPOINTMENT:

You will be asked to change from your street clothes into a hospital gown and pants. The only street clothes you will be able to keep on will be your socks and underwear. (Note: women will also be asked to remove your bra.) All jewelry and watches will need to be removed prior to your scan. This includes all body piercings. If you are unable to remove ANY piece of jewelry, please inform the scheduler when scheduling your appointment. Hearing aids can NOT be worn inside the scanner. Please do not remove your hearing aid until the technologist has spoken with you about your scan. The magnetic field will damage them. No billfolds or purses will be allowed in the scan rooms. In addition to hazards of unknown metal objects, the magnetic field will wipe out credit cards, bankcards, security card, etc. Although we have a locked box for storage, you do so at your own risk. We are not responsible for items left in the dressing rooms. We strongly encourage you to leave valuable items at home.

The MRI scanner is noisy, so you will be given earplugs for your exam.

If you are claustrophobic, please let your doctor know. They may be able to prescribe a sedative to help you relax. The MRI department can not prescribe or administer sedatives. If you take a sedative, you will need someone to drive you to and from your appointment.

Please be sure to bring your [REDACTED] and photo ID for check in

Cosign Order Info

Action	Created on	Responsible Provider	Signed by	Signed on
--------	------------	----------------------	-----------	-----------

[REDACTED]				
------------	--	--	--	--

Order Tracking Information

+3222

MRI BRAIN (surveillance)

+3297

[page 14 of 22]
Results

MRI BRAIN WO/W CONTRAST

PACS Images

Show images for MRI BRAIN WO/W CONTRAST

MRI BRAIN WO/W CONTRAST

Status: Final result Visible to patient: No (Not Released) Next appt: [REDACTED] Order: [REDACTED] in Family Practice

Dx: CANCER CHEMOTHERAPY; GLIOBLASTOMA MUL...

Details

Reading Physician

Reading Date

Result Priority

+4039

Narrative & Impression

EXAM: MRI BRAIN WO/W CONTRAST

EXAM DATE AND TIME: [REDACTED] +4035

HISTORY: Status post surgical resection of a left temporal lobe glioblastoma multiforme.

TECHNIQUE:

MRI brain without and with contrast using the following pulse sequences:

1. Sagittal and axial T1.
2. Axial T2 and axial FLAIR.
3. Axial gradient echo and axial DWI.
4. Axial, coronal, and sagittal T1 postcontrast.

Uneventful intravenous administration of 5 cc Gadavist gadolinium contrast.

COMPARISON: MRI brain [REDACTED] and [REDACTED]
+3859 +3674

FINDINGS:

Patient is status post a left temporal lobe surgical resection for primary CNS malignancy. FLAIR hypointense surgical resection cavity within the left temporal subcortical white matter measures 1.3 x 0.8 cm in greatest axial dimension and is unchanged. There is a mild degree of confluent left temporal and left posterior frontal subcortical and periventricular deep white matter bright FLAIR signal which is unchanged dating back to at least [REDACTED]. There is mild ex vacuo dilatation of the left lateral ventricle temporal horn indicating chronic volume loss which is unchanged.

There is no further white matter disease on FLAIR imaging. On noncontrast imaging, brain parenchyma otherwise demonstrates normal morphology and signal. Ventricular system and basilar cisterns are maintained. There is no acute intraparenchymal or extra axial fluid collection. Intracranial vascular flow voids are maintained. Gradient echo imaging is normal. DWI is normal.

[page 15 of 22]
On postcontrast imaging lying deep to the left temporal craniotomy is a mild degree of linear enhancement consistent with postsurgical granulation tissue. This is unchanged. There is a mild degree of peripheral enhancement surrounding the surgical resection cavity. This is unchanged and of no clinical significance.

On postcontrast imaging, there is no further abnormal parenchymal, dural, or leptomeningeal enhancement. Intracranial deep venous vasculature is normal. Intracranial deep venous vasculature is patent.

Paranasal sinuses are clear. Mastoid air cells are clear. There is no concerning infiltrative marrow process.

IMPRESSION:

1. No evidence of residual/recurrent left temporal lobe primary CNS malignancy status post surgical resection.
2. Stable left temporal - frontal white matter disease presumably reflecting postsurgical gliosis and treatment sequelae.
3. No acute stroke or hemorrhage.

+3674

+3674

Specimen Collected:

Last Resulted:

Encounter

[View Parent Encounter](#)

Future Appts

Upcoming Appointments

Date / Time	Provider	Department	Dept Phone	Special Notes
[Redacted]				

Result Information

Status: Final result (Exam End:

Provider Status: Reviewed

+4035

Patient Release Status:

This result is not viewable by the patient.

Imaging Information

Exam Information

Performed Procedure

MRI BRAIN WO/W CONTRAST

Study Status

Final

Begin Time

End Time

Staff Information

Technologist

Transcriptionist

N/A

Assigned Physician(s)

N/A

Assigned Pool(s)

N/A

+4035

+4035

[page 16 of 22]
Verification Information

Signed By

Signed On

+4039

All Reviewers List

Order

MRI BRAIN WO AND W CONTRAST

Print Result Report

report

Order Report

Order Details

Order Tracking Information

MRI BRAIN WO/W CONTRAST

+4035

[page 17 of 22]
+4214
Office Visit [REDACTED]
[REDACTED]

Provider: [REDACTED]
Primary diagnosis: CANCER CHEMOTHERAPY
Reason for Visit: FOLLOW UP CARE

Progress Notes

[REDACTED] Hematology and Oncology
ONCOLOGY PROGRESS NOTE

ONCOLOGY HISTORY

Patient of [REDACTED] Per [REDACTED] last note:
Dx: [REDACTED] F with GBM, gr 4
+2 - [REDACTED] had left temporal craniotomy and resection and path revealed grade 4 GBM. 4 gliadel wafers were placed in the resection cavity. A f/u MRI [REDACTED] +3 showed sequela of resection.
Tx: XRT completed [REDACTED] +79
Tx: Temodar started [REDACTED] +132

SUBJECTIVE

Continues to do excellently
No seizure or seizure-like episodes per the patient and her husband
Had a impacted wisdom tooth removed on [REDACTED] +2740
Denies f/c, pain, SOB/DOE, dysuria, LE edema, HA, new neurologic sx

OBJECTIVE

BP 120/72 (BP Location: LA-LEFT ARM, BP Patient Position: SITTING, Cuff Size: Standard Adult) | Pulse 84 | Temp 98 °F (36.7 °C) | Wt 114 lb 9.6 oz (52 kg) | LMP [REDACTED] | BMI 21.36 kg/m²

ECOG 1
NAD
Anicteric sclera
CTAB
NIS1S2, RRR
+BS, NT/ND, soft
No LE edema
No cervical, axillary, or supraclavicular lymphadenopathy
Normal affect and mood, mildly anxious
CN grossly intact

Recent Labs	+4210	+4195	4181	+3545
WBCCORRECT	3.45*	3.35*	2.26*	3.62*
ANC	1.59*	1.18*	0.80*	--
BAND	--	--	--	0.11
HGB	13.8	13.4	13.5	13.3
HCT	40.5	40.5	40.4	39.5
MCV	108.6*	109.8*	109.2*	108.2*
PLT	219	215	180	189

< > = values in this interval not displayed.

Recent Labs	+4210	+4195	+4181
CR	0.80	0.63	0.6

[page 18 of 22]
Recent Labs	+4210	+4195	+4181
ALT	24	18	21
TBILI	0.3	0.2	0.2

Recent Labs	+4181	+3580	+3359
DIL	19.9	13.6	16.7

IMAGING

Brain MRI [REDACTED] +4035

1. No evidence of residual/recurrent left temporal lobe primary CNS malignancy status post surgical resection.
2. Stable left temporal - frontal white matter disease presumably reflecting postsurgical gliosis and treatment sequelae.
3. No acute stroke or hemorrhage.

ASSESSMENT/PLAN

Per [REDACTED] note:

[REDACTED] GBM with no evidence of active disease and excellent tolerance of temozolomide.
No recurrence of seizure, meds managed by neurology.
She overall feels chemo very tolerable and wants to continue with temodar.
Have had many discussions about concept of chemotherapy holiday, she continues to decline and wants to remain on therapy. Have had detailed discussion emphasizing QOL and that we may not improve OS by continuing temodar at this time. She indicates good understanding and feels her current QOL is excellent and wants to continue on therapy. She has already outlived the statistics for GBM. Have discussed in theory possible risks of MDS or AML with prolonged temodar. She and husband indicate good understanding but want to continue with the temodar.
continue on q5 weeks schedule given prior delay for low ANC.
Reviewed labs in detail, ANC meets parameters today.

At this point, the patient is on temozolomide indefinitely until progression or poor tolerance.

Negative brain scan [REDACTED] +4035

Continue with temozolomide, cycle length: 6 weeks for counts
CBC check every 3 weeks moving forward
ANC cutoff is 1000

Defer the next cycle for 2 weeks due to tooth extraction, refill pick up on [REDACTED] at [REDACTED] to get CBC drawn on [REDACTED]

Then q6m f/u with scans

I spent 25 minutes with the patient today, of which >50% of the time was used for face-to-face counseling. The patient's questions and concerns were addressed.

Progress Notes

Accompanied by: Spouse/Significant Other,

Chaperone offered: no.

[page 19 of 22]
VITALS DETAILS

Blood Pressure taken using: adult's cuff - left arm sitting
Weight: with shoes

CURRENT HEALTH AND MEDS

Last Mammogram: [REDACTED] +3943
LAST PAP SMEAR: [REDACTED] +3082
LAST COLONOSCOPY: none found
LAST FOBT: [REDACTED] +3949
@LASTBONEDENSITY@
Asprin: No
Patient requests the following refills: None
Patient Prefers: [REDACTED] pharmacy

HEALTH HISTORY

Component	Value	Date	
WBCCORRECT	3.45 (L)	[REDACTED]	+4210
NEUT	1.59 (L)	[REDACTED]	+4210
ANC	1.59 (L)	[REDACTED]	+4210
HGB	13.8	[REDACTED]	+4210
HCT	40.5	[REDACTED]	+4210
MCV	108.6 (H)	[REDACTED]	+4210
PLT	219	[REDACTED]	+4210

Panel Support Tool Reviewed: PST patient handout given.

Other Notes

All notes

Instructions

Return in 6 weeks ([REDACTED]) for Telephone Visit.

It was nice to see you today.

[page 20 of 22]
- Have a wonderful holiday season!

+4214

If you have any questions or concerns, please feel free to call the clinic at the number below.

Regards,

After hours, weekends, and holidays, please call the [REDACTED] nurse at [REDACTED]

IMPORTANT INFORMATION FOR PATIENTS RECEIVING CHEMOTHERAPY

Chemotherapy may weaken your defenses and make you more susceptible to unusual medical problems. Taking chemotherapy as an outpatient places more responsibility on you.

Please call *immediately* if you experience any of the problems described below or have questions:

1. Any temperature over 100.4 degrees orally.
2. Vomiting more than 3 times per day or in large amounts.
3. Diarrhea: over 3-4 watery stools per day.
4. Abnormal bruising, nose bleeds, or blood in your stool or urine.
5. Mouth sores that prevent eating.
6. Exposure to chicken pox if you have never had the disease or vaccination.

After Visit Summary (Automatic SnapShot taken [REDACTED])

+4214

Additional Documentation

Vitals: BP 120/72 (BP Location: LA-LEFT ARM, BP Patient Position: SITTING, Cuff Size: Standard Adult)
Pulse 84 Temp 98 °F (36.7 °C) Wt 114 lb 9.6 oz (52 kg) LMF [REDACTED] MI 21.36 kg/m²
BSA 1.5 m² Pain Sc 0 (scale 0-10) (Edu: Yes) More Vitals

Flowsheets: Tx Plan Communication

Encounter Info: History, Allergies, Billing Report, Detailed Report

Vitals Recorded in This Encounter

+4214

BP: 120/72
Cuff Size: Standard Adult
BP Location: LA-LEFT ARM
Pulse: 84
Temp: 98 °F (36.7 °C)
Weight: 114 lb 9.6 oz (52 kg)
Pain Score: 0 (0-10)
Pain Edu?: Y

No questionnaires available.

[page 21 of 22]
Linked Episodes

ONCOLOGY CHEMOTHERAPY Noted +498

Orders Placed

None

Medication Changes

As of

None +4214

Visit Diagnoses

CANCER CHEMOTHERAPY Z51.11
GLIOBLASTOMA MULTIFORME, TEMPORAL LOBE C71.2

[page 22 of 22]
Transcription

Type	ID	Date and Time	Dictating Provider
Diagnostic imaging			

MRI

+162

+161

MRI OF THE BRAIN

HISTORY

glioblastoma multiforme status post resection, radiation therapy. Increasing difficulty with word-finding. Evaluate for progression. Please compare to earlier.

PROCEDURE

T1 sagittal. T1 axial. Proton density T2 axial. FLAIR axial. Subsequently, the patient was given 15 mL of Magnevist 469 mg/mL. Post gadolinium SPGR axial views through the brain. No complications.

FINDINGS

+121

Compared to the last MRI dated

Normal signal void vessels base of the skull. The fourth ventricle remains midline. Ventricular system, cisternal spaces and sulci unchanged. Previously described left posterior temporal lobe resection cavity looks stable. Previously described left dural enhancement overlying the site of the left temporal craniotomy is again redemonstrated unchanged. The ring enhancing lesion now measures about 3.5 cm in maximum size certainly not increased. No other new abnormal enhancing lesions are seen. Ipsilateral enlargement of the left lateral ventricle when compared to the right side stable.

IMPRESSION

+121

Essentially stable-appearing MRI of the brain dating back to Left temporal lobe resection cavity with area of some thick peripheral enhancement mild medial extension not significantly changed. Again the differential is some either superimposed granulation tissue or a combination of granulation tissue plus recurrent and/or residual tumor. Other findings similar.

Electronically Signed by:

MRI BRAIN OTHER.

Order:

Status: Final result Visible to patient: No (Not Released) Next appt:

Dx: CA BRAIN, CEREBRUM, GBM surgery

Last Resulted:

Source: NCI Genomic Data Commons file 6742150b-0de8-4269-80ab-7fd4621751fd (ER0366 ER-B0DO Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).